Gene-level copy-number profile of tumor specimen TCGA-OR-A5K2-01A from TCGA case TCGA-OR-A5K2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 32.8 years (11,970 days).
Specimen TCGA-OR-A5K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.740ed154-d2e9-41cb-ad4f-db90423f4d6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K2-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f267de37-8808-4562-b25e-dbf8d0593284

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 545; copy number 2: 9,576; copy number 3: 27,063; copy number 4: 15,948; copy number 5: 6,423; copy number 6: 139; copy number 7: 23; copy number 8: 89; copy number 10: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K2-01A-11D-A29H-01): tumor purity 0.83, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 120 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:14,143,342–15,496,353, 22 genes, copy number 8 (within-gene range 6–8): TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1.
- chr5:20,967,211–21,779,522, 8 genes, copy number 7: AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–21,884,310, 1 gene, copy number 7: HSPD1P1.
- chr6:130,366,017–131,584,332, 9 genes, copy number 8 (within-gene range 2–8): TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1.
- chr6:134,897,874–135,260,933, 10 genes, copy number 7: MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1.
- chr6:135,301,568–135,307,158, 1 gene, copy number 7: AL049552.1.
- chr6:136,206,478–136,250,335, 2 genes, copy number 8: AL138828.2, MTFR2.
- chr6:136,342,281–136,934,866, 15 genes, copy number 8 (within-gene range 3–8): MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA.
- chr6:146,802,359–149,076,990, 22 genes, copy number 8–10 (within-gene range 3–10): KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1, STXBP5, AL355365.1, YAP1P1, SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST.
- chr6:151,088,103–151,228,447, 1 gene, copy number 8 (within-gene range 2–8): AL138733.1.
- chr6:151,196,681–152,759,765, 26 genes, copy number 8: AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11, MYCT1, HSPD1P16, VIP.
- chr6:155,253,139–155,314,493, 3 genes, copy number 7: AL596202.1, TFB1M, CLDN20.

Autosomal genes at a single copy (total copy number 1): 545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
